CCDI case PBCHWK — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Spinal cord, cranial nerves, and other parts of central nervous system.
https://portal.gdc.cancer.gov/cases/843ade79-5939-4ad8-8798-8f43fababb11

Demographics
Sex at birth: male; Race: black or african american.

Diagnoses (1)
1. Pilocytic astrocytoma: ICD-O-3 morphology code: 9421/1; Tissue or organ of origin: Spinal cord; Age at diagnosis: 16.2 years (5,903 days).

Biospecimens (3 samples)
- Sample 0DSEYY: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DSEZB: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DSEZL: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
